Somatic mutation profile of tumor specimen C3N-01754-02 (aliquot CPT0162990007) from CPTAC case C3N-01754, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 64.1 years (23,404 days).
Specimen C3N-01754-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8173e151-3936-4c91-934c-8d74e19fb23a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01754-31 (Blood Derived Normal), aliquot CPT0163080002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/404aded8-0e7c-4f67-8c97-9a79d6333c4c

The open-access MAF lists 138 somatic variants for this specimen: 89 protein-altering or splice-affecting, 33 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 33, Intron 10, Nonsense Mutation 6, Frame Shift Del 5, Frame Shift Ins 4, Splice Site 2, 5'UTR 2, 3'Flank 1, 5'Flank 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TBK1 | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as rs1064797170; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 338/625 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTN3 | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 29/373 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs760434035, COSV59748536; called by muse, mutect2
- ADAMTS3 | c.3410C>T p.A1137V | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs778309362; called by muse, mutect2, varscan2
- AGXT | c.125G>C p.G42A | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as CM093785; called by muse, mutect2, varscan2
- ANGPT1 | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 21/406 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.14); catalogued as COSV52440135; called by muse, mutect2
- ANK2 | c.11825G>A p.R3942H | Missense Mutation (SNP) | VAF 42/277 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs542400709, COSV52170394; called by muse, mutect2, varscan2
- BHLHE22 | c.221_260del p.G74Afs*18 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs778657494; called by mutect2, pindel
- CCR4 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs752494781, COSV58384563; called by muse, mutect2, varscan2
- CLMN | c.1549C>T p.R517C | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs370362581, COSV100113051; called by muse, mutect2
- CNTNAP5 | c.2681C>G p.P894R | Missense Mutation (SNP) | VAF 39/295 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99081558; called by muse, mutect2, varscan2
- CPS1 | c.2872C>A p.L958I | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV51810433, COSV99242654; called by muse, mutect2
- DOCK6 | c.5258G>A p.R1753H | Missense Mutation (SNP) | VAF 69/393 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778267289; called by muse, mutect2, varscan2
- DVL3 | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 74/470 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.494); catalogued as rs749291784; called by muse, mutect2, varscan2
- DYSF | c.2221T>C p.Y741H | Missense Mutation (SNP) | VAF 142/432 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs1421869976; called by muse, mutect2, varscan2
- EXOSC10 | c.1414C>T p.R472W | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs761495943; called by muse, mutect2, varscan2
- FBXL18 | c.1612C>A p.L538I | Missense Mutation (SNP) | VAF 169/277 reads (61%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV66107436; called by muse, mutect2, varscan2
- FOLR3 | c.186_188del p.K62del | In Frame Del (DEL) | VAF 286/839 reads (34%) | catalogued as rs759309921; called by pindel, varscan2
- FSTL5 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1415403789; called by muse, mutect2, varscan2
- GGTLC1 | c.413C>A p.A138E | Missense Mutation (SNP) | VAF 155/667 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV53848989; called by muse, mutect2, varscan2
- GOLGA6L22 | c.1106G>C p.R369P | Missense Mutation (SNP) | VAF 25/421 reads (6%) | SIFT deleterious (0.03); catalogued as rs1162053353; called by muse, mutect2, varscan2
- GRHL1 | c.149G>T p.S50I | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61406684; called by muse, mutect2, varscan2
- GRM8 | c.79A>G p.M27V | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs374316613; called by muse, mutect2, varscan2
- HOXB1 | c.692C>A p.A231D | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53318296; called by muse, mutect2, varscan2
- HPSE2 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65196662, COSV65203139; called by muse, mutect2, varscan2
- IGSF10 | c.3097C>T p.R1033W | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs145551493; called by muse, mutect2, varscan2
- KLRK1 | c.534-1G>C p.X178_splice | Splice Site (SNP) | VAF 6/58 reads (10%) | catalogued as COSV53700012; called by muse, mutect2
- MECOM | c.680G>A p.S227N (on ENST00000468789 / NM_001105078.4; = p.S415N on NM_004991.4) | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1446914453; called by muse, mutect2, varscan2
- MEOX1 | c.57G>A p.W19* | Nonsense Mutation (SNP) | VAF 23/75 reads (31%) | catalogued as COSV59356730; called by muse, mutect2, varscan2
- MMP16 | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 18/110 reads (16%) | catalogued as COSV54162310; called by muse, mutect2, varscan2
- MXRA5 | c.8473A>C p.I2825L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as COSV54222845; called by muse, varscan2
- MYH11 | c.-16G>A | Splice Region (SNP) | VAF 58/290 reads (20%) | catalogued as rs752672406, COSV55563916; called by muse, mutect2, varscan2
- OR4M1 | c.678G>C p.K226N | Missense Mutation (SNP) | VAF 65/352 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV60062531; called by muse, mutect2, varscan2
- PCDHB4 | c.1207G>A p.V403I | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as rs1289332669; called by muse, mutect2, varscan2
- PGR | c.1574A>G p.Y525C | Missense Mutation (SNP) | VAF 64/952 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs888043891; called by muse, mutect2
- PHRF1 | c.1841G>A p.R614Q (on ENST00000264555 / NM_001286581.2; = p.R613Q on NM_020901.4) | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752856198, COSV52754578; called by muse, mutect2, varscan2
- RECQL5 | c.1016C>A p.S339Y | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100512348; called by muse, mutect2, varscan2
- RTL1 | c.2503C>T p.R835W | Missense Mutation (SNP) | VAF 48/352 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs537765084, COSV66016881; called by muse, mutect2, varscan2
- SLC23A2 | c.1585G>A p.V529I | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.129); catalogued as rs923180188, COSV57773125; called by muse, mutect2, varscan2
- SLC24A4 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 89/400 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs778472920, COSV54107783; called by muse, mutect2, varscan2
- SLC37A1 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs1252302932, COSV61402626; called by muse, mutect2, varscan2
- SRC | c.1571C>G p.T524R | Missense Mutation (SNP) | VAF 64/267 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV62441465; called by muse, mutect2, varscan2
- TKTL1 | c.1648G>A p.V550I | Missense Mutation (SNP) | VAF 118/181 reads (65%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as rs146609649, COSV54214189; called by muse, mutect2, varscan2
- ZNF184 | c.1160A>C p.E387A | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV104393459; called by muse, mutect2, varscan2
- ZNF184 | c.1159G>T p.E387* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as COSV53003307, COSV99279912; called by muse, mutect2, varscan2
- ZNF208 | c.2722G>T p.E908* | Nonsense Mutation (SNP) | VAF 16/120 reads (13%) | catalogued as COSV68103657; called by muse, varscan2
- ZNF831 | c.654C>A p.D218E | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs765839282; called by muse, mutect2, varscan2
- ACER1 | c.350G>A p.R117K | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2
- AKNA | c.235G>T p.G79W | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- CCNL1 | c.1364A>T p.D455V | Missense Mutation (SNP) | VAF 61/202 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CEP126 | c.2984G>A p.S995N | Missense Mutation (SNP) | VAF 120/171 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- CNTN6 | c.3034del p.L1012Ffs*6 | Frame Shift Del (DEL) | VAF 11/60 reads (18%) | called by mutect2, pindel, varscan2
- CTTN | c.872A>G p.E291G | Missense Mutation (SNP) | VAF 24/527 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by muse, mutect2
- DIDO1 | c.6470G>A p.R2157H | Missense Mutation (SNP) | VAF 151/432 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- FAT2 | c.2681A>T p.E894V | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- FCRL2 | c.189dup p.F64Ifs*13 | Frame Shift Ins (INS) | VAF 12/101 reads (12%) | called by mutect2, pindel, varscan2
- FMN2 | c.2837C>G p.P946R | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.286); called by mutect2, varscan2
- HERC4 | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- IRF6 | c.836C>A p.P279H | Missense Mutation (SNP) | VAF 88/303 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KIF25 | c.76G>T p.D26Y | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.025); called by muse, varscan2
- KRTAP5-2 | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 24/148 reads (16%) | PolyPhen benign (0.161); called by muse, mutect2, varscan2
- LEPR | c.3326T>C p.L1109S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- LVRN | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- LYST | c.8696G>A p.G2899E | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MROH1 | c.4484G>T p.G1495V | Missense Mutation (SNP) | VAF 297/999 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MUC13 | c.835_848del p.D279* | Frame Shift Del (DEL) | VAF 29/124 reads (23%) | called by mutect2, pindel, varscan2
- MUC17 | c.8030C>A p.A2677D | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.246); called by muse, mutect2
- MYH13 | c.989A>C p.E330A | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MYH15 | c.1783G>T p.A595S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- NOTCH1 | c.5923G>A p.G1975S | Missense Mutation (SNP) | VAF 101/274 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- NPAS2 | c.2313G>C p.L771F | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- OR51G1 | c.524T>C p.V175A | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- PDZRN3 | c.2378G>A p.G793E | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2
- PHKB | c.468dup p.T157Yfs*4 | Frame Shift Ins (INS) | VAF 18/175 reads (10%) | called by mutect2, varscan2
- PIGG | c.779C>G p.P260R | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- PIK3R3 | c.803del p.G268Vfs*10 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | called by mutect2, pindel, varscan2
- PLXNA2 | c.4738C>T p.R1580W | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRR23C | c.731_732del p.R244Pfs*55 | Frame Shift Del (DEL) | VAF 37/105 reads (35%) | called by pindel, varscan2
- PSG8 | c.804C>G p.N268K | Missense Mutation (SNP) | VAF 23/348 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.964); called by muse, mutect2
- SLC45A4 | c.961G>T p.E321* (on ENST00000517878 / NM_001286646.2; = p.E270* on NM_001080431.2) | Nonsense Mutation (SNP) | VAF 101/295 reads (34%) | called by muse, mutect2, varscan2
- SYNDIG1 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBXT | c.704A>G p.D235G | Missense Mutation (SNP) | VAF 45/326 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TEAD3 | c.942C>A p.F314L | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TICAM1 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TMEM233 | c.153dup p.I52Hfs*32 | Frame Shift Ins (INS) | VAF 43/170 reads (25%) | called by mutect2, pindel, varscan2
- TMEM50A | c.466dup p.W156Lfs*34 | Frame Shift Ins (INS) | VAF 18/183 reads (10%) | called by mutect2, pindel, varscan2
- TNRC6A | c.6-2A>C p.X2_splice | Splice Site (SNP) | VAF 50/152 reads (33%) | called by muse, mutect2, varscan2
- TPR | c.6166G>A p.E2056K | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- TRIM77 | c.1353A>T p.*451Yext*? | Nonstop Mutation (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- ARVCF | c.2052C>T p.A684= | Silent (SNP) | VAF 19/141 reads (13%) | called by muse, mutect2, varscan2
- BBS2 | c.1296C>T p.P432= | Silent (SNP) | VAF 40/344 reads (12%) | called by muse, mutect2, varscan2
- BHMG1 | c.840T>A p.P280= | Silent (SNP) | VAF 47/316 reads (15%) | called by muse, mutect2, varscan2
- C16orf71 | c.429C>T p.P143= | Silent (SNP) | VAF 49/352 reads (14%) | catalogued as rs777657805; called by muse, mutect2, varscan2
- C4orf54 | c.3387G>T p.G1129= | Silent (SNP) | VAF 34/223 reads (15%) | called by muse, mutect2, varscan2
- DAAM2 | c.1110G>C p.T370= | Silent (SNP) | VAF 66/208 reads (32%) | catalogued as COSV51306421; called by muse, mutect2, varscan2
- EIF3F | c.552G>C p.V184= | Silent (SNP) | VAF 24/140 reads (17%) | called by muse, mutect2, varscan2
- F13B | c.897T>C p.H299= | Silent (SNP) | VAF 20/80 reads (25%) | called by muse, mutect2, varscan2
- FAM111B | c.1914G>A p.T638= | Silent (SNP) | VAF 11/105 reads (10%) | catalogued as rs1475144812; called by muse, mutect2, varscan2
- FUT4 | c.240G>T p.G80= | Silent (SNP) | VAF 74/546 reads (14%) | catalogued as rs952321211, COSV62468896; called by muse, mutect2, varscan2
- IGHV4-39 | c.234T>C p.S78= | Silent (SNP) | VAF 144/254 reads (57%) | catalogued as rs1280246884; called by muse, mutect2, varscan2
- IRAK2 | c.516G>A p.S172= | Silent (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2
- KCNT2 | c.2097A>G p.L699= | Silent (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- KLHL33 | c.474G>A p.L158= | Silent (SNP) | VAF 40/260 reads (15%) | catalogued as COSV60727860; called by muse, mutect2, varscan2
- LACTBL1 | c.495C>T p.D165= (on ENST00000618559; = p.D210= on NM_001289974.2) | Silent (SNP) | VAF 90/224 reads (40%) | catalogued as rs762555965; called by muse, mutect2, varscan2
- LEFTY2 | c.939G>T p.P313= | Silent (SNP) | VAF 64/427 reads (15%) | catalogued as COSV100832683; called by muse, mutect2, varscan2
- LRP1 | c.8103C>T p.F2701= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as rs368477109; called by muse, mutect2, varscan2
- LRRIQ4 | c.633G>A p.T211= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as rs772006375; called by muse, mutect2, varscan2
- MUC17 | c.2844T>C p.P948= | Silent (SNP) | VAF 22/150 reads (15%) | called by muse, mutect2, varscan2
- MUC5B | c.5130C>T p.R1710= | Silent (SNP) | VAF 51/204 reads (25%) | called by muse, mutect2, varscan2
- MYH1 | c.669C>T p.I223= | Silent (SNP) | VAF 41/413 reads (10%) | catalogued as COSV99875336; called by muse, mutect2, varscan2
- NKX2-2 | c.522C>A p.I174= | Silent (SNP) | VAF 73/521 reads (14%) | called by muse, mutect2, varscan2
- OR2AG1 | c.288C>A p.G96= | Silent (SNP) | VAF 39/232 reads (17%) | catalogued as rs1447727072; called by muse, mutect2, varscan2
- PCDHB6 | c.1686G>A p.P562= | Silent (SNP) | VAF 130/684 reads (19%) | catalogued as rs782507289, COSV50696238; called by muse, mutect2, varscan2
- PCDHGA7 | c.285C>A p.I95= | Silent (SNP) | VAF 71/191 reads (37%) | called by muse, mutect2, varscan2
- PDPK1 | c.1611G>A p.R537= | Silent (SNP) | VAF 79/301 reads (26%) | called by muse, mutect2, varscan2
- PTCHD3 | c.594C>A p.S198= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV101438964; called by muse, mutect2, varscan2
- SLC45A4 | c.960G>T p.L320= (on ENST00000517878 / NM_001286646.2; = p.L269= on NM_001080431.2) | Silent (SNP) | VAF 101/298 reads (34%) | called by muse, mutect2, varscan2
- TTN | c.63099T>A p.S21033= (on ENST00000591111; = p.S13609= on NM_003319.4) | Silent (SNP) | VAF 18/126 reads (14%) | called by muse, mutect2, varscan2
- UTRN | c.1155A>G p.E385= | Silent (SNP) | VAF 18/132 reads (14%) | called by muse, mutect2
- VPS53 | c.2247G>A p.P749= | Silent (SNP) | VAF 51/167 reads (31%) | catalogued as rs374460563; called by muse, mutect2, varscan2
- YARS2 | c.546G>A p.L182= | Silent (SNP) | VAF 118/458 reads (26%) | catalogued as rs1383891711; called by muse, mutect2, varscan2
- ZNF503 | c.1335G>A p.A445= | Silent (SNP) | VAF 43/189 reads (23%) | catalogued as COSV65307377; called by muse, mutect2, varscan2
- ATG4D | c.1123-36C>G | Intron (SNP) | VAF 79/293 reads (27%) | called by muse, mutect2, varscan2
- CYB5A | c.288+10A>G | Intron (SNP) | VAF 16/100 reads (16%) | called by muse, mutect2
- DECR2 | c.149+562A>T | Intron (SNP) | VAF 14/183 reads (8%) | called by muse, mutect2
- GLYATL1 | n.145C>G | RNA (SNP) | VAF 26/514 reads (5%) | called by muse, mutect2
- GRAMD1B | c.374+4322_374+4329del | Intron (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel, varscan2
- GRM5 | c.662-75649C>G | Intron (SNP) | VAF 23/171 reads (13%) | called by muse, mutect2, varscan2
- KCTD10 | c.527+15G>A | Intron (SNP) | VAF 31/153 reads (20%) | catalogued as rs771437976; called by muse, mutect2, varscan2
- KRT8 | c.*65G>A | 3'UTR (SNP) | VAF 33/257 reads (13%) | catalogued as rs773173782; called by muse, mutect2, varscan2
- MROH8 | c.-286A>T | 5'UTR (SNP) | VAF 18/86 reads (21%) | catalogued as COSV54121733; called by muse, mutect2, varscan2
- OR6P1 | chr1:158562647 T>C | 3'Flank (SNP) | VAF 24/106 reads (23%) | catalogued as rs1231409197; called by muse, mutect2, varscan2
- POTEM | c.811-1184G>C | Intron (SNP) | VAF 36/308 reads (12%) | called by mutect2, varscan2
- RBM24 | c.348-881G>T | Intron (SNP) | VAF 31/261 reads (12%) | called by muse, mutect2, varscan2
- REG1B | c.433+27G>T | Intron (SNP) | VAF 23/168 reads (14%) | called by muse, mutect2, varscan2
- SOAT2 | c.-11G>A | 5'UTR (SNP) | VAF 53/380 reads (14%) | catalogued as rs1380337399; called by muse, mutect2, varscan2
- TIMP1 | c.453+211C>T | Intron (SNP) | VAF 11/57 reads (19%) | catalogued as rs1365012528; called by muse, mutect2, varscan2
- UBA6 | chr4:67701365 del GTAGATGGAACCAAAGTCCAGAA | 5'Flank (DEL) | VAF 26/222 reads (12%) | called by mutect2, pindel, varscan2
